Somatic mutation profile of tumor specimen TCGA-BJ-A0ZB-01A (aliquot TCGA-BJ-A0ZB-01A-11D-A10S-08) from TCGA case TCGA-BJ-A0ZB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 66.8 years (24,415 days).
Specimen TCGA-BJ-A0ZB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57a0dd65-c121-4b59-9fbd-af18d81f87c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0ZB-10A (Blood Derived Normal), aliquot TCGA-BJ-A0ZB-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9c911f0-28b1-42a9-b625-6e93473df4e0

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 23, Silent 5, Splice Region 2, Nonstop Mutation 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAMTS18 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759290262, COSV51407885; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs1270048823, COSV54446530; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2846C>A p.S949Y | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV54998786; called by muse, mutect2, varscan2
- AMOTL2 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51438860; called by muse, mutect2
- ANK2 | c.4096G>A p.E1366K | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52159521; called by muse, mutect2, varscan2
- ASAP1 | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.089); catalogued as COSV63048121; called by muse, mutect2
- ASRGL1 | c.230T>C p.M77T | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV57124510; called by muse, mutect2, varscan2
- CACNA1E | c.4624T>C p.W1542R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62392910; called by muse, mutect2, varscan2
- CAMKV | c.225G>A p.K75= | Splice Region (SNP) | VAF 4/59 reads (7%) | catalogued as COSV56554600, COSV56555224; called by muse, mutect2
- CCT2 | c.713T>G p.L238R | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54740049; called by muse, mutect2, varscan2
- CHAT | c.387T>G p.S129= | Splice Region (SNP) | VAF 18/34 reads (53%) | catalogued as COSV60324492; called by muse, mutect2, varscan2
- CSF3R | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 147/340 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779227407, COSV58966490; called by muse, mutect2, varscan2
- DNASE2 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53434968; called by muse, mutect2, varscan2
- EIF4G2 | c.1577T>C p.I526T | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as COSV60596979; called by muse, mutect2, varscan2
- EPS15L1 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs771110967, COSV50168525; called by muse, mutect2, varscan2
- ETF1 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.197); catalogued as COSV62127283; called by muse, mutect2
- FAM135B | c.2966T>C p.V989A | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV52722449; called by muse, mutect2, varscan2
- GRID2 | c.3022T>C p.*1008Rext*29 | Nonstop Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as COSV56201403; called by muse, mutect2, varscan2
- ITGAL | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 89/240 reads (37%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.991); catalogued as COSV63322062; called by muse, mutect2, varscan2
- OR1N2 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.253); catalogued as COSV65460561; called by muse, mutect2
- OR51V1 | c.165G>C p.E55D | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.999); catalogued as COSV58315024; called by muse, mutect2, varscan2
- RUNX1T1 | c.1627G>C p.D543H (on ENST00000265814 / NM_001198628.1; = p.D516H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56137534; called by muse, mutect2
- SCAF4 | c.3343G>C p.E1115Q | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as rs1331644756, COSV54256046; called by muse, mutect2
- TK1 | c.632A>C p.K211T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.069); catalogued as COSV56745653; called by muse, mutect2, varscan2
- TMEM109 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV50005340; called by muse, mutect2
- ACAD10 | c.2395-9_2397del p.X799_splice | Splice Site (DEL) | VAF 31/92 reads (34%) | called by mutect2, pindel, varscan2
- TEX11 | c.573_576dup p.A193Sfs*17 (on ENST00000344304; = p.A178Sfs*17 on NM_031276.3) | Frame Shift Ins (INS) | VAF 33/43 reads (77%) | called by mutect2, pindel, varscan2
- HHIPL2 | c.705C>T p.A235= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV58564985; called by muse, mutect2, varscan2
- OR8H2 | c.477C>T p.N159= | Silent (SNP) | VAF 111/311 reads (36%) | catalogued as rs554066587, COSV100542521; called by muse, mutect2, varscan2
- PPHLN1 | c.1083C>T p.H361= | Silent (SNP) | VAF 26/336 reads (8%) | catalogued as rs778909777, COSV56730684; called by muse, mutect2
- SPEM2 | c.1131C>T p.D377= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1481309702, COSV61603843; called by muse, mutect2, varscan2
- TMEM131L | c.3519T>C p.S1173= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as COSV53644055; called by muse, mutect2, varscan2
